Somatic mutation profile of tumor specimen BLGSP-71-08-00432-01B (aliquot BLGSP-71-08-00432-01B-01E-A512-33) from CGCI case BLGSP-71-08-00432, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female.
Specimen BLGSP-71-08-00432-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ca6830-7e54-4182-9966-57421ecf2566.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00432-10A (Blood Derived Normal), aliquot BLGSP-71-08-00432-10A-01D-A512-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d622690a-7e62-4499-a14f-58a5e924b88e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF4A1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51511043; called by muse, mutect2, varscan2
- FAS | c.*2+2T>C | Splice Site (SNP) | VAF 11/22 reads (50%) | catalogued as CS994527, COSV58239800, COSV58240147; called by muse, mutect2, varscan2
- GNA13 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71475427; called by muse, mutect2, varscan2
- VCAN | c.1674A>G p.E558= | Silent (SNP) | VAF 40/102 reads (39%) | called by muse, varscan2
